Gene-level copy-number profile of tumor specimen TCGA-V4-A9F4-01A from TCGA case TCGA-V4-A9F4, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 42.0 years (15,332 days).
Specimen TCGA-V4-A9F4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UVM.ffeec777-6964-4409-b332-ec94736d49f1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V4-A9F4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/754b22ad-3732-4f56-b9ae-f39472a8980e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,473; copy number 2: 52,162; copy number 3: 2,151; copy number 4: 1,271; copy number 5: 280; copy number 6: 483.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V4-A9F4-01A-11D-A39V-01): tumor purity 0.91, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 763 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:167,607–17,737,556, 317 genes, copy number 5–6 (broad region; genes not listed).
- chr6:27,404,010–30,955,636, 253 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr6:46,096,004–58,438,364, 193 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,086. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
